Somatic mutation profile of tumor specimen HCM-SANG-0289-C15-01B (aliquot HCM-SANG-0289-C15-01B-01D-A79M-36) from HCMI case HCM-SANG-0289-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0289-C15-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff969d3b-d5cd-4d62-ae6a-2a7db6e6ae94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0289-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0289-C15-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35471f2a-7b2c-421c-b01d-6bd6acb023ea

The open-access MAF lists 393 somatic variants for this specimen: 278 protein-altering or splice-affecting, 96 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 251, Silent 96, Nonsense Mutation 14, Intron 12, Frame Shift Del 7, RNA 3, 5'Flank 2, In Frame Del 2, Frame Shift Ins 2, 3'UTR 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.225_243del p.A76Cfs*64 | Frame Shift Del (DEL) | VAF 216/433 reads (50%) | catalogued as rs730881674; ClinVar: pathogenic; called by mutect2, varscan2
- GLB1 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 133/463 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776327443, CM070942; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 91/270 reads (34%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 104/366 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ACTR10 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as rs754722393; called by muse, mutect2, varscan2
- ADAM12 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV64107225; called by muse, mutect2
- ADAMTSL2 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 63/620 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1445226341, COSV63205331; called by muse, mutect2, varscan2
- ADD2 | c.928C>A p.Q310K | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.561); catalogued as COSV52469610; called by muse, mutect2, varscan2
- ADRA1B | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 92/401 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1396771876; called by muse, mutect2, varscan2
- ANK3 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 46/499 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1290278926, COSV55055997; called by muse, mutect2
- ARHGAP26 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1485178041; called by muse, mutect2
- ARHGAP45 | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 95/470 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.361); catalogued as rs1433144481; called by muse, mutect2, varscan2
- ARHGEF7 | c.1979C>A p.P660H (on ENST00000375741 / NM_001113511.2; = p.P482H on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/498 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99522311; called by muse, mutect2, varscan2
- ARPP21 | c.1201A>G p.S401G | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs1196024489; called by muse, mutect2, varscan2
- ASTN1 | c.1345T>G p.F449V | Missense Mutation (SNP) | VAF 67/376 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV56087061; called by muse, mutect2, varscan2
- ASTN2 | c.2282A>G p.K761R (on ENST00000313400 / NM_001365069.1; = p.K710R on NM_014010.5) | Missense Mutation (SNP) | VAF 99/377 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs974202503, COSV100524865, COSV100531251; called by muse, mutect2, varscan2
- ATL1 | c.532T>G p.L178V | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV100612942; called by muse, mutect2
- ATP13A1 | c.2675G>A p.R892Q | Missense Mutation (SNP) | VAF 130/699 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs147877135; called by muse, mutect2, varscan2
- BCAT1 | c.527A>C p.K176T | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.035); catalogued as rs376524284, COSV53907997; called by muse, mutect2, varscan2
- C4orf54 | c.1822G>A p.G608R | Missense Mutation (SNP) | VAF 33/373 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs955919554; called by muse, mutect2
- CACNG3 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 73/321 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV50065182, COSV99135432; called by muse, mutect2, varscan2
- CDC37L1 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 58/302 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs773728369; called by muse, mutect2, varscan2
- CNTNAP3 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 38/526 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs1415418901, COSV52664320; called by muse, mutect2
- CSMD2 | c.8617C>T p.R2873C | Missense Mutation (SNP) | VAF 58/546 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53960112; called by muse, mutect2
- DCHS1 | c.4262G>A p.R1421Q | Missense Mutation (SNP) | VAF 72/617 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as rs1470639252, COSV100201988; called by muse, mutect2, varscan2
- DGKQ | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 179/553 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1291917906; called by muse, mutect2, varscan2
- DHRS7C | c.796G>A p.V266M (on ENST00000330255 / NM_001220493.2; = p.V265M on NM_001105571.3) | Missense Mutation (SNP) | VAF 81/379 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs774255168, COSV57651134; called by muse, varscan2
- DHX57 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 51/364 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs774769962, COSV54891886; called by muse, mutect2, varscan2
- DNAH9 | c.6242A>G p.K2081R | Missense Mutation (SNP) | VAF 112/359 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs752058038; called by muse, mutect2, varscan2
- DPP10 | c.522A>C p.E174D | Missense Mutation (SNP) | VAF 25/283 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV100062068; called by muse, mutect2
- DSTYK | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs562238251; called by muse, mutect2, varscan2
- ENPP2 | c.1933G>A p.V645I (on ENST00000075322 / NM_001040092.3; = p.V697I on NM_006209.5) | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs879040983, COSV50010024, COSV50030870; called by muse, mutect2, varscan2
- EPG5 | c.6766G>A p.D2256N | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.56); catalogued as rs746819105, COSV56356428; called by muse, mutect2, varscan2
- ERCC2 | c.137C>G p.T46S | Missense Mutation (SNP) | VAF 11/384 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.385); catalogued as COSV55538550; called by muse, mutect2
- FAM168B | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 97/408 reads (24%) | SIFT tolerated, low confidence (0.92); PolyPhen probably damaging (0.92); catalogued as rs1434131763, COSV66304980; called by muse, mutect2, varscan2
- FAM47A | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 130/335 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.942); catalogued as rs1555968153, COSV60496368, COSV60499742; called by muse, mutect2, varscan2
- FAM47C | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 42/359 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs782414838, COSV100792281, COSV63727724; called by muse, mutect2, varscan2
- FAT4 | c.8657T>G p.L2886R | Missense Mutation (SNP) | VAF 65/263 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58674921, COSV58711887; called by muse, mutect2, varscan2
- FBN2 | c.3701C>T p.T1234M | Missense Mutation (SNP) | VAF 50/287 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368105987; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLG | c.8542G>A p.G2848R | Missense Mutation (SNP) | VAF 96/739 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs767188996; called by muse, mutect2, varscan2
- FLG | c.7534A>C p.S2512R | Missense Mutation (SNP) | VAF 47/364 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs773788883, COSV64241812, COSV64245918; called by muse, mutect2, varscan2
- FLNA | c.6019G>A p.V2007M (on ENST00000369850 / NM_001110556.2; = p.V1999M on NM_001456.3) | Missense Mutation (SNP) | VAF 106/277 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as rs200956777, COSV61042743; called by muse, mutect2, varscan2
- FOXD4L4 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 150/844 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.025); catalogued as rs1462016648; called by muse, mutect2, varscan2
- FREM2 | c.2437G>A p.V813M | Missense Mutation (SNP) | VAF 85/416 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as rs200490975; called by muse, mutect2, varscan2
- FSCB | c.1046A>C p.E349A | Missense Mutation (SNP) | VAF 18/430 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV61219360; called by muse, mutect2
- GPR174 | c.424T>C p.W142R | Missense Mutation (SNP) | VAF 98/274 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52133370; called by muse, mutect2, varscan2
- GPX8 | c.528A>C p.Q176H | Missense Mutation (SNP) | VAF 69/307 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV57057719; called by muse, mutect2, varscan2
- GRM8 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 32/354 reads (9%) | catalogued as COSV58849712; called by muse, mutect2
- GSE1 | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 101/511 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1001784439; called by muse, mutect2, varscan2
- H2AC8 | c.227_229del p.K76del | In Frame Del (DEL) | VAF 93/314 reads (30%) | catalogued as rs780617468; called by pindel, varscan2
- HDX | c.1568T>G p.L523R | Missense Mutation (SNP) | VAF 101/283 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.203); catalogued as COSV52982960; called by muse, mutect2, varscan2
- HNRNPAB | c.596T>C p.F199S | Missense Mutation (SNP) | VAF 48/330 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201874623; called by muse, mutect2, varscan2
- HTR1E | c.739T>G p.F247V | Missense Mutation (SNP) | VAF 88/360 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV59507370; called by muse, mutect2, varscan2
- IFFO1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 128/1025 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1284341379; called by muse, mutect2, varscan2
- IMPG2 | c.1600A>C p.S534R | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV51986244, COSV99514564; called by muse, mutect2, varscan2
- IRF6 | c.302A>G p.K101R | Missense Mutation (SNP) | VAF 40/420 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.086); catalogued as CD133895; called by muse, mutect2
- ITIH3 | c.1516C>T p.R506C | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs770349939; called by muse, mutect2
- JAKMIP3 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752511214; called by muse, mutect2
- KCNS2 | c.1267C>T p.L423F | Missense Mutation (SNP) | VAF 99/418 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); catalogued as rs773134157; called by muse, mutect2, varscan2
- KHDRBS3 | c.267A>C p.E89D | Missense Mutation (SNP) | VAF 139/459 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV100878494; called by muse, mutect2, varscan2
- KIF13B | c.2554G>A p.D852N | Missense Mutation (SNP) | VAF 89/1226 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs766419855; called by muse, mutect2
- KIF16B | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 45/327 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as rs750526216; called by muse, mutect2, varscan2
- KPRP | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 64/526 reads (12%) | catalogued as rs528347017; called by muse, mutect2, varscan2
- KRBA1 | c.1915_1926del p.S639_P642del | In Frame Del (DEL) | VAF 190/560 reads (34%) | catalogued as rs772332239; called by mutect2, varscan2
- KRT40 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 124/546 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.061); catalogued as rs779513103, COSV66696570; called by muse, mutect2, varscan2
- LIPI | c.1412T>G p.L471R | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100754048; called by muse, mutect2
- LRRN3 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57821020; called by muse, mutect2, varscan2
- LYPD2 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 73/505 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as rs779763852; called by muse, mutect2, varscan2
- MAGEC2 | c.665A>G p.E222G | Missense Mutation (SNP) | VAF 37/369 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV55997596; called by muse, mutect2, varscan2
- MAGI2 | c.1913C>G p.P638R | Missense Mutation (SNP) | VAF 97/410 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.944); catalogued as COSV100835526; called by muse, mutect2, varscan2
- MAP3K1 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 86/362 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs1490957244, COSV68123265; called by muse, mutect2, varscan2
- MBL2 | c.410A>C p.K137T | Missense Mutation (SNP) | VAF 50/335 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100906255; called by muse, mutect2, varscan2
- MIDEAS | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 26/540 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99679096; called by muse, mutect2
- MROH9 | c.2362C>T p.R788* | Nonsense Mutation (SNP) | VAF 20/218 reads (9%) | catalogued as rs1447165676; called by muse, mutect2
- NCAN | c.3566C>T p.A1189V | Missense Mutation (SNP) | VAF 113/527 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs542871862, COSV53049190, COSV53050814; called by muse, mutect2, varscan2
- NELL1 | c.1193G>A p.G398E | Missense Mutation (SNP) | VAF 58/284 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV54299224; called by muse, mutect2, varscan2
- NFASC | c.2972C>T p.T991M | Missense Mutation (SNP) | VAF 63/453 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs541866977; called by muse, varscan2
- NLGN2 | c.456C>T p.D152= | Splice Region (SNP) | VAF 47/216 reads (22%) | catalogued as rs776313858; called by muse, mutect2, varscan2
- NPAP1 | c.2792C>T p.P931L | Missense Mutation (SNP) | VAF 99/439 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV61512086; called by muse, mutect2, varscan2
- NTM | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 76/274 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.021); catalogued as rs368362251; called by muse, mutect2, varscan2
- OR4K5 | c.560T>A p.L187H | Missense Mutation (SNP) | VAF 69/457 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60003984, COSV60004319; called by muse, mutect2, varscan2
- OR4X1 | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 73/347 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60723378; called by muse, mutect2, varscan2
- OR52K2 | c.46T>A p.L16M | Missense Mutation (SNP) | VAF 19/311 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57835917; called by muse, mutect2
- OR5AS1 | c.829T>A p.F277I | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV57980635; called by muse, mutect2, varscan2
- P2RY8 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 153/798 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.778); catalogued as COSV67176734; called by muse, mutect2, varscan2
- PCDHB4 | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 75/733 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.716); catalogued as COSV52025300; called by muse, mutect2, varscan2
- PCDHB6 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 22/460 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50700216; called by muse, mutect2
- PDGFD | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56369808; called by muse, mutect2
- PIGM | c.516C>G p.F172L | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63636161; called by muse, mutect2
- PIGO | c.1998G>T p.K666N | Missense Mutation (SNP) | VAF 118/464 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53053391; called by muse, mutect2, varscan2
- PLCXD3 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 73/325 reads (22%) | catalogued as COSV60607905; called by muse, mutect2, varscan2
- PLK4 | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 73/362 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs1296213930; called by muse, mutect2, varscan2
- PLSCR5 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs372370688, COSV71649018; called by muse, mutect2, varscan2
- POLR3C | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 35/382 reads (9%) | catalogued as COSV61937625; called by muse, mutect2
- PRKG2 | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 26/436 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as rs371926830; called by muse, mutect2
- PTPRF | c.5363G>A p.R1788Q | Missense Mutation (SNP) | VAF 9/257 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63443741, COSV63444400; called by muse, mutect2
- PXMP4 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 36/396 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as rs772966200, COSV54133999; called by muse, mutect2
- RERE | c.3778G>A p.A1260T | Missense Mutation (SNP) | VAF 75/631 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs376576951; called by muse, mutect2, varscan2
- RGS4 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 75/237 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs771715416, COSV63357940; called by muse, mutect2, varscan2
- RPUSD4 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 17/446 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1565316712, COSV53599214; called by muse, mutect2
- SCN5A | c.3584G>A p.R1195H (on ENST00000333535 / NM_198056.3; = p.R1194H on NM_000335.5) | Missense Mutation (SNP) | VAF 43/615 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199473596, CM098020, COSV100350649, COSV61124717; ClinVar: not provided; called by muse, mutect2
- SERPINA1 | c.347T>G p.I116S | Missense Mutation (SNP) | VAF 29/558 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as CM900180; called by muse, mutect2
- SGO2 | c.3490G>A p.V1164I | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs529668035, COSV63417571; called by muse, mutect2, varscan2
- SH3D19 | c.1504G>A p.V502I | Missense Mutation (SNP) | VAF 40/362 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs1197857349, COSV100455479; called by muse, mutect2, varscan2
- SHISA9 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 42/332 reads (13%) | catalogued as rs1459953538, COSV69633132; called by muse, mutect2, varscan2
- SIGLEC1 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 71/420 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200340665; called by muse, mutect2, varscan2
- SLFN11 | c.2279G>C p.C760S | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100390570; called by muse, mutect2, varscan2
- SMG9 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 61/398 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs777451698; called by muse, mutect2, varscan2
- SOX5 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 40/728 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs894279426; called by muse, mutect2
- SRCAP | c.6226G>A p.E2076K | Missense Mutation (SNP) | VAF 59/444 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52678042, COSV99351126; called by muse, mutect2, varscan2
- SRP68 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 45/411 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs377369805; called by muse, varscan2
- STX5 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 67/336 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs542193132, COSV53678619; called by muse, mutect2, varscan2
- STXBP5L | c.1513C>A p.Q505K | Missense Mutation (SNP) | VAF 54/259 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as COSV99875418; called by muse, mutect2, varscan2
- SYNE1 | c.8034A>C p.E2678D (on ENST00000367255 / NM_182961.4; = p.E2685D on NM_033071.3) | Missense Mutation (SNP) | VAF 91/357 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.179); catalogued as rs1477042059; called by muse, mutect2, varscan2
- TAF1C | c.2539C>T p.R847C | Missense Mutation (SNP) | VAF 49/563 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.528); catalogued as rs200180697, COSV58986982; called by muse, mutect2
- TAF7L | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 90/284 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.749); catalogued as rs759737945; called by muse, mutect2, varscan2
- TBX18 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 131/726 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as rs890027291; called by muse, mutect2, varscan2
- TCF24 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 42/305 reads (14%) | SIFT tolerated (0.08); catalogued as rs998913206; called by muse, mutect2, varscan2
- TCHH | c.5393G>A p.R1798H | Missense Mutation (SNP) | VAF 20/528 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.747); catalogued as rs1248071972; called by muse, mutect2
- TENT5D | c.394C>G p.Q132E | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV100382770; called by muse, mutect2, varscan2
- TFEC | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 18/471 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1390461837; called by muse, mutect2
- TMEM225 | c.560C>A p.S187Y | Missense Mutation (SNP) | VAF 35/363 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs1188719982; called by muse, mutect2
- TNRC18 | c.3101C>T p.P1034L | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs764873435; called by muse, mutect2
- TNXB | c.11162G>A p.G3721D (on ENST00000647633; = p.G3474D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/702 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1562782112; called by muse, mutect2
- TPRX1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 60/627 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs769592547; called by muse, mutect2
- TRIML2 | c.1014A>C p.K338N | Missense Mutation (SNP) | VAF 150/516 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.94); catalogued as COSV58714561, COSV58718244, COSV58720356; called by muse, mutect2, varscan2
- U2SURP | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 12/390 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV67533673; called by muse, mutect2
- VCAN | c.7420G>A p.A2474T | Missense Mutation (SNP) | VAF 24/253 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs756069926, COSV54095630; called by muse, mutect2, varscan2
- VPS13B | c.10309G>T p.A3437S | Missense Mutation (SNP) | VAF 46/346 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs879217228; called by muse, mutect2, varscan2
- WNK1 | c.3728C>G p.P1243R (on ENST00000315939 / NM_018979.4; = p.P996R on NM_014823.3) | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as rs762713931, COSV60046434; called by muse, mutect2, varscan2
- ZNF135 | c.932C>A p.S311Y (on ENST00000313434 / NM_001289401.2; = p.S323Y on NM_003436.4) | Missense Mutation (SNP) | VAF 98/442 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100536520; called by muse, mutect2, varscan2
- ZNF324B | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 43/926 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as rs1157149647; called by muse, mutect2
- ZNF730 | c.783T>G p.C261W | Missense Mutation (SNP) | VAF 69/364 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101659653; called by muse, mutect2, varscan2
- ZPR1 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.095); catalogued as rs529843898, COSV57064906; called by muse, mutect2
- ADAMTSL3 | c.321T>G p.N107K | Missense Mutation (SNP) | VAF 58/295 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- ADGRB3 | c.94A>C p.T32P | Missense Mutation (SNP) | VAF 30/504 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.193); called by muse, mutect2
- ARHGAP20 | c.440A>C p.N147T | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.718); called by muse, mutect2
- ATM | c.1737G>C p.W579C | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- B4GALNT4 | c.2482G>A p.V828M | Missense Mutation (SNP) | VAF 36/448 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2
- BIRC6 | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 15/484 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); called by muse, mutect2
- BRCA1 | c.3062G>A p.S1021N | Missense Mutation (SNP) | VAF 19/358 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.272); called by muse, mutect2
- BTBD3 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNA1B | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 63/862 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- CACNB4 | c.1115del p.P372Qfs*20 | Frame Shift Del (DEL) | VAF 17/174 reads (10%) | called by mutect2, pindel, varscan2
- CAPN9 | c.1876C>T p.Q626* | Nonsense Mutation (SNP) | VAF 37/161 reads (23%) | called by muse, varscan2
- CASS4 | c.1424A>C p.N475T | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- CCL1 | c.28T>C p.C10R | Missense Mutation (SNP) | VAF 40/411 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CD163L1 | c.2947G>A p.V983I | Missense Mutation (SNP) | VAF 15/546 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2
- CD1A | c.242A>G p.K81R | Missense Mutation (SNP) | VAF 68/417 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CDC27 | c.579A>T p.L193F | Missense Mutation (SNP) | VAF 41/390 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CDH11 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CFAP43 | c.3434T>G p.F1145C | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CFAP54 | c.5071A>C p.I1691L | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHN1 | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CHUK | c.130_131del p.K44Vfs*17 | Frame Shift Del (DEL) | VAF 61/263 reads (23%) | called by mutect2, pindel, varscan2
- COL4A1 | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2
- CSMD1 | c.7180G>A p.G2394R (on ENST00000520002; = p.G2393R on NM_033225.6) | Missense Mutation (SNP) | VAF 14/293 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYLC1 | c.992A>G p.E331G | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CYP19A1 | c.1216T>G p.F406V | Missense Mutation (SNP) | VAF 98/382 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- DDI1 | c.570G>C p.K190N | Missense Mutation (SNP) | VAF 79/352 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DHCR24 | c.165G>T p.W55C | Missense Mutation (SNP) | VAF 14/470 reads (3%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.962); called by muse, mutect2
- DNAH7 | c.2641C>A p.L881M | Missense Mutation (SNP) | VAF 48/250 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- DPEP3 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.42); called by muse, mutect2
- DPP10 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DPP9 | c.1961A>G p.N654S (on ENST00000598800; = p.N683S on NM_139159.5) | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); called by muse, mutect2
- DYRK1B | c.335A>T p.E112V | Missense Mutation (SNP) | VAF 18/696 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- EXOC3L2 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 89/719 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- FAM47C | c.2849dup p.L951Afs*4 | Frame Shift Ins (INS) | VAF 95/333 reads (29%) | called by mutect2, pindel, varscan2
- FAM71C | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 69/393 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- FLG | c.5035G>C p.E1679Q | Missense Mutation (SNP) | VAF 35/341 reads (10%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- FOXO4 | c.1406A>G p.D469G | Missense Mutation (SNP) | VAF 13/402 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FYN | c.1270C>A p.Q424K | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FZD5 | c.251T>G p.F84C | Missense Mutation (SNP) | VAF 19/462 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GABRA4 | c.913A>G p.S305G | Missense Mutation (SNP) | VAF 66/325 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GALNT3 | c.1070T>C p.I357T | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- GBA2 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 52/309 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- GGCX | c.107_108del p.K36Tfs*5 | Frame Shift Del (DEL) | VAF 50/538 reads (9%) | called by mutect2, pindel
- GLG1 | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 23/460 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.879); called by muse, mutect2
- GON4L | c.5468C>T p.A1823V | Missense Mutation (SNP) | VAF 77/315 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- GPC6 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRIK1 | c.1541A>C p.N514T | Missense Mutation (SNP) | VAF 15/303 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- GRIP1 | c.3097A>C p.N1033H (on ENST00000359742 / NM_001379345.1; = p.N981H on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/670 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2
- GRK5 | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 73/302 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HEATR4 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 60/329 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HERC2 | c.8680C>T p.Q2894* | Nonsense Mutation (SNP) | VAF 73/423 reads (17%) | called by muse, mutect2, varscan2
- HMCN1 | c.13719G>T p.L4573F | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HTR2A | c.1185T>G p.I395M | Missense Mutation (SNP) | VAF 21/306 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.387); called by muse, mutect2
- ITGA9 | c.2896T>C p.F966L | Missense Mutation (SNP) | VAF 40/461 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- JAKMIP1 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 15/497 reads (3%) | called by muse, mutect2
- KCNA10 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 76/357 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNJ3 | c.893T>C p.I298T | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLC1 | c.1284G>T p.M428I | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.355); called by muse, mutect2
- KLK8 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 64/331 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- LEFTY1 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 159/761 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.031); called by muse, mutect2
- LEMD1 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- LOXHD1 | c.1691T>C p.L564P | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2
- LPCAT2 | c.1166A>G p.K389R | Missense Mutation (SNP) | VAF 56/264 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- LRFN5 | c.889A>G p.R297G | Missense Mutation (SNP) | VAF 78/363 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- LRRC40 | c.421A>C p.K141Q | Missense Mutation (SNP) | VAF 8/209 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2
- MACF1 | c.5862C>G p.S1954R | Missense Mutation (SNP) | VAF 32/289 reads (11%) | called by muse, mutect2, varscan2
- MAGEL2 | c.1349T>C p.V450A | Missense Mutation (SNP) | VAF 140/844 reads (17%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- MEF2A | c.1354C>A p.P452T (on ENST00000557942 / NM_001319206.2; = p.P446T on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/524 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MFSD12 | c.845T>A p.I282K | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.251); called by muse, mutect2
- MTOR | c.6946C>T p.R2316* | Nonsense Mutation (SNP) | VAF 29/270 reads (11%) | called by muse, mutect2, varscan2
- MUC6 | c.657del p.S220Afs*17 | Frame Shift Del (DEL) | VAF 75/555 reads (14%) | called by mutect2, pindel, varscan2
- MYOD1 | c.445A>T p.I149F | Missense Mutation (SNP) | VAF 25/664 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NAV3 | c.1673A>C p.K558T | Missense Mutation (SNP) | VAF 25/355 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2
- NEFL | c.1265C>A p.S422Y | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- NFASC | c.3103C>T p.P1035S | Missense Mutation (SNP) | VAF 51/271 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- NOCT | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 55/594 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NOTCH1 | c.3422A>G p.Y1141C | Missense Mutation (SNP) | VAF 63/629 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NRG1 | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 64/310 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.066); called by mutect2, varscan2
- NRK | c.4601T>C p.L1534P | Missense Mutation (SNP) | VAF 78/207 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUAK1 | c.1956A>C p.Q652H | Missense Mutation (SNP) | VAF 82/319 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- OAZ1 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 133/426 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR10C1 | c.668T>C p.L223P (on ENST00000622521; = p.L221P on NM_013941.3) | Missense Mutation (SNP) | VAF 196/720 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- OR10J5 | c.11A>C p.K4T | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR11H12 | c.850G>T p.G284W | Missense Mutation (SNP) | VAF 31/330 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- OR2A2 | c.724T>A p.S242T | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2A25 | c.313A>G p.S105G | Missense Mutation (SNP) | VAF 21/296 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.036); called by muse, mutect2
- OR2M2 | c.439T>G p.F147V | Missense Mutation (SNP) | VAF 57/293 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- OR4D10 | c.806A>C p.K269T | Missense Mutation (SNP) | VAF 144/424 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- OR5D3P | c.731A>G p.K244R | Missense Mutation (SNP) | VAF 44/285 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- OR6N1 | c.400A>C p.T134P | Missense Mutation (SNP) | VAF 75/350 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- PABPC4L | c.1069T>G p.L357V | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- PCDHB2 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 50/438 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- PIGR | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2
- PLS3 | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 112/334 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- POSTN | c.1679A>G p.Q560R | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- POU3F3 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PRAMEF4 | c.1415A>T p.E472V | Missense Mutation (SNP) | VAF 27/279 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2
- PRDM9 | c.846A>C p.E282D | Missense Mutation (SNP) | VAF 45/334 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRRC2B | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PURA | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 91/482 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- RAP1GAP2 | c.65G>C p.G22A | Missense Mutation (SNP) | VAF 72/258 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RAP1GDS1 | c.929T>C p.F310S (on ENST00000408927 / NM_001100427.2; = p.F311S on NM_021159.5) | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2
- RGS9BP | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 78/854 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2
- ROBO2 | c.608G>C p.C203S | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ROBO2 | c.2330T>C p.I777T | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- ROGDI | c.645+1G>C p.X215_splice | Splice Site (SNP) | VAF 60/467 reads (13%) | called by muse, mutect2, varscan2
- RPTOR | c.326A>C p.Q109P | Missense Mutation (SNP) | VAF 24/317 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- SASH3 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); called by muse, mutect2
- SCN9A | c.5790del p.D1931Ifs*31 (on ENST00000303354; = p.D1920Ifs*31 on NM_002977.3) | Frame Shift Del (DEL) | VAF 29/162 reads (18%) | called by mutect2, pindel, varscan2
- SETD7 | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 22/471 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.3); called by muse, mutect2
- SIPA1L3 | c.747C>G p.H249Q | Missense Mutation (SNP) | VAF 68/638 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC22A14 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 124/448 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC6A13 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 139/448 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- SLCO4C1 | c.383T>C p.I128T | Missense Mutation (SNP) | VAF 67/273 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SLCO4C1 | c.105G>T p.L35F | Missense Mutation (SNP) | VAF 90/378 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); called by muse, mutect2
- STAG1 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 11/309 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- STK33 | c.187A>G p.K63E | Missense Mutation (SNP) | VAF 73/239 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SYNE1 | c.10909C>A p.Q3637K | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TBX5 | c.360A>C p.K120N | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- TERB1 | c.949A>G p.I317V | Missense Mutation (SNP) | VAF 10/296 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- TEX2 | c.3287A>G p.D1096G (on ENST00000583097 / NM_001288733.2; = p.D1103G on NM_018469.5) | Missense Mutation (SNP) | VAF 27/332 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- TMEM273 | c.187T>G p.L63V | Missense Mutation (SNP) | VAF 22/406 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2
- TMPRSS4 | c.1067G>T p.C356F | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TOE1 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- TPR | c.4621C>T p.Q1541* | Nonsense Mutation (SNP) | VAF 21/458 reads (5%) | called by muse, mutect2
- TRIML1 | c.1033G>T p.V345L | Missense Mutation (SNP) | VAF 57/361 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIML2 | c.1172T>C p.L391P | Missense Mutation (SNP) | VAF 113/440 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TSHZ3 | c.856T>C p.S286P | Missense Mutation (SNP) | VAF 79/425 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TUT4 | c.3470T>G p.V1157G | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- TYRP1 | c.649G>T p.G217* | Nonsense Mutation (SNP) | VAF 79/376 reads (21%) | called by muse, mutect2, varscan2
- UBR5 | c.4993G>A p.D1665N | Missense Mutation (SNP) | VAF 17/386 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); called by muse, mutect2
- UGT3A1 | c.404A>C p.K135T | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- UGT3A2 | c.152A>T p.H51L | Missense Mutation (SNP) | VAF 33/367 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UNC13B | c.4703G>A p.R1568K | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- VPS51 | c.1907G>A p.R636H | Missense Mutation (SNP) | VAF 40/503 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2
- WDR17 | c.3272C>G p.A1091G | Missense Mutation (SNP) | VAF 23/337 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.05); called by muse, mutect2
- WNT9A | c.257T>G p.V86G | Missense Mutation (SNP) | VAF 183/727 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ZBED1 | c.1640_1682del p.M547Rfs*12 | Frame Shift Del (DEL) | VAF 192/924 reads (21%) | called by mutect2, pindel
- ZDBF2 | c.5962G>T p.G1988W | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF416 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 96/355 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF705A | c.222A>T p.Q74H | Missense Mutation (SNP) | VAF 62/652 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- ZNF804A | c.784T>C p.S262P | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.006); called by muse, mutect2
- ZW10 | c.101_102insA p.K35Qfs*3 | Frame Shift Ins (INS) | VAF 103/381 reads (27%) | called by mutect2, pindel, varscan2
- AC100868.1 | c.1848C>A p.A616= | Silent (SNP) | VAF 106/605 reads (18%) | catalogued as COSV51848108; called by muse, mutect2, varscan2
- AHCTF1 | c.1026C>G p.A342= (on ENST00000366508; = p.A316= on NM_015446.5) | Silent (SNP) | VAF 15/461 reads (3%) | catalogued as COSV58254955; called by muse, mutect2
- AHNAK2 | c.1461C>T p.H487= | Silent (SNP) | VAF 61/433 reads (14%) | catalogued as rs371425536; called by muse, mutect2, varscan2
- AKR1E2 | c.366C>T p.S122= | Silent (SNP) | VAF 30/356 reads (8%) | called by muse, mutect2
- ALAS1 | c.1860G>C p.V620= | Silent (SNP) | VAF 104/391 reads (27%) | called by muse, mutect2, varscan2
- BMP8B | c.198C>T p.A66= | Silent (SNP) | VAF 65/620 reads (10%) | called by muse, mutect2, varscan2
- C1orf94 | c.294A>G p.R98= | Silent (SNP) | VAF 34/243 reads (14%) | called by muse, mutect2, varscan2
- CAPN9 | c.1344G>A p.T448= | Silent (SNP) | VAF 37/306 reads (12%) | catalogued as rs763285582; called by muse, mutect2, varscan2
- CD101 | c.1998G>A p.R666= | Silent (SNP) | VAF 23/388 reads (6%) | catalogued as COSV56717820; called by muse, mutect2
- CHAD | c.1023C>T p.D341= | Silent (SNP) | VAF 37/593 reads (6%) | catalogued as rs773421154, COSV99366082; called by muse, mutect2
- CNTNAP5 | c.1674A>C p.G558= | Silent (SNP) | VAF 35/199 reads (18%) | called by muse, mutect2, varscan2
- COL22A1 | c.2481G>T p.L827= | Silent (SNP) | VAF 38/563 reads (7%) | called by muse, mutect2
- COL4A5 | c.2277T>G p.P759= | Silent (SNP) | VAF 117/251 reads (47%) | catalogued as rs1415670653; called by muse, mutect2, varscan2
- COL5A1 | c.3627C>T p.F1209= | Silent (SNP) | VAF 49/504 reads (10%) | catalogued as rs748000980, COSV65667530; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CPN1 | c.519C>T p.N173= | Silent (SNP) | VAF 52/464 reads (11%) | catalogued as rs1429754269, COSV64942264; called by muse, mutect2
- CRACDL | c.906C>T p.P302= | Silent (SNP) | VAF 69/617 reads (11%) | called by muse, mutect2, varscan2
- CRTAM | c.984C>T p.H328= | Silent (SNP) | VAF 40/228 reads (18%) | called by muse, mutect2, varscan2
- CSMD3 | c.10086T>A p.S3362= (on ENST00000297405 / NM_001363185.1; = p.S3193= on NM_052900.3) | Silent (SNP) | VAF 90/330 reads (27%) | called by muse, mutect2, varscan2
- CTNNA3 | c.2556T>C p.A852= | Silent (SNP) | VAF 89/486 reads (18%) | called by muse, mutect2, varscan2
- CYLC2 | c.516A>G p.K172= | Silent (SNP) | VAF 73/380 reads (19%) | catalogued as COSV100872470; called by muse, mutect2, varscan2
- DDI1 | c.852A>G p.R284= | Silent (SNP) | VAF 20/513 reads (4%) | called by muse, mutect2
- DERPC | c.831C>T p.P277= | Silent (SNP) | VAF 30/265 reads (11%) | called by muse, mutect2, varscan2
- DKK1 | c.255C>T p.C85= | Silent (SNP) | VAF 20/404 reads (5%) | catalogued as rs987275148; called by muse, mutect2
- DNAJC5B | c.76C>T p.L26= | Silent (SNP) | VAF 63/326 reads (19%) | catalogued as COSV99395516; called by muse, mutect2, varscan2
- DOC2A | c.540T>C p.C180= | Silent (SNP) | VAF 13/305 reads (4%) | called by muse, mutect2
- DVL1 | c.312G>A p.P104= | Silent (SNP) | VAF 75/642 reads (12%) | catalogued as rs760489981; called by muse, mutect2, varscan2
- ECD | c.1725C>T p.T575= | Silent (SNP) | VAF 19/294 reads (6%) | catalogued as rs1346370464, COSV100624862; called by muse, mutect2
- EEFSEC | c.174G>A p.V58= | Silent (SNP) | VAF 79/826 reads (10%) | called by muse, mutect2
- EYS | c.2185A>C p.R729= | Silent (SNP) | VAF 59/288 reads (20%) | called by muse, mutect2, varscan2
- FEZF1 | c.24G>T p.A8= | Silent (SNP) | VAF 64/247 reads (26%) | called by muse, mutect2, varscan2
- FIGN | c.684G>A p.P228= | Silent (SNP) | VAF 52/269 reads (19%) | catalogued as rs779110711, COSV60766857; called by muse, mutect2, varscan2
- FLG | c.11721C>T p.R3907= | Silent (SNP) | VAF 52/288 reads (18%) | catalogued as rs374091552; called by muse, mutect2, varscan2
- FLG | c.10221T>C p.T3407= | Silent (SNP) | VAF 35/699 reads (5%) | catalogued as rs1430005853; called by muse, mutect2
- FNDC1 | c.15C>T p.A5= | Silent (SNP) | VAF 70/338 reads (21%) | called by muse, mutect2, varscan2
- FOXG1 | c.282C>T p.D94= | Silent (SNP) | VAF 51/301 reads (17%) | catalogued as rs1483249092; called by muse, mutect2, varscan2
- FOXL2 | c.648C>T p.A216= | Silent (SNP) | VAF 122/562 reads (22%) | catalogued as rs975695593; called by muse, mutect2, varscan2
- FREM3 | c.435C>T p.Y145= | Silent (SNP) | VAF 196/584 reads (34%) | called by muse, varscan2
- GALNT17 | c.1534T>C p.L512= | Silent (SNP) | VAF 14/406 reads (3%) | catalogued as COSV61147304; called by muse, mutect2
- GLI1 | c.468C>T p.P156= | Silent (SNP) | VAF 195/626 reads (31%) | called by muse, mutect2, varscan2
- GRM1 | c.1203A>G p.E401= | Silent (SNP) | VAF 38/212 reads (18%) | catalogued as COSV99266979; called by muse, mutect2
- GRM5 | c.2496C>T p.N832= | Silent (SNP) | VAF 32/416 reads (8%) | catalogued as rs1415000435; called by muse, mutect2
- GRM7 | c.1989C>T p.G663= | Silent (SNP) | VAF 100/301 reads (33%) | catalogued as rs775811460; called by muse, mutect2, varscan2
- H1-5 | c.360G>A p.K120= | Silent (SNP) | VAF 102/500 reads (20%) | catalogued as rs201327319; called by muse, mutect2, varscan2
- IGDCC3 | c.879C>T p.I293= | Silent (SNP) | VAF 18/596 reads (3%) | called by muse, mutect2
- IGHG3 | c.1308C>T p.P436= | Silent (SNP) | VAF 55/316 reads (17%) | catalogued as rs945735123; called by muse, mutect2, varscan2
- MALRD1 | c.1185A>G p.E395= | Silent (SNP) | VAF 43/201 reads (21%) | called by muse, mutect2, varscan2
- MUC16 | c.2607T>C p.T869= | Silent (SNP) | VAF 45/276 reads (16%) | called by muse, mutect2, varscan2
- MUC19 | c.921T>G p.T307= | Silent (SNP) | VAF 17/373 reads (5%) | catalogued as COSV66447245; called by muse, mutect2
- MUC6 | c.2382C>T p.T794= | Silent (SNP) | VAF 144/352 reads (41%) | catalogued as rs751069493; called by muse, varscan2
- MYO10 | c.1251C>A p.I417= | Silent (SNP) | VAF 44/474 reads (9%) | called by muse, mutect2
- NCKAP5 | c.4614A>G p.K1538= | Silent (SNP) | VAF 16/381 reads (4%) | catalogued as COSV100494907; called by muse, mutect2
- NEB | c.7803C>T p.S2601= | Silent (SNP) | VAF 43/390 reads (11%) | catalogued as COSV99413190; called by muse, mutect2, varscan2
- NIPBL | c.1209A>C p.T403= | Silent (SNP) | VAF 13/387 reads (3%) | called by muse, mutect2
- NKAPL | c.364C>T p.L122= | Silent (SNP) | VAF 33/432 reads (8%) | called by muse, mutect2
- NLRC4 | c.2121C>T p.V707= | Silent (SNP) | VAF 36/304 reads (12%) | called by muse, mutect2, varscan2
- NPR3 | c.615C>T p.S205= | Silent (SNP) | VAF 48/504 reads (10%) | called by muse, mutect2
- OBSCN | c.18267G>A p.A6089= | Silent (SNP) | VAF 147/505 reads (29%) | catalogued as rs759601682; called by muse, mutect2, varscan2
- OR4K2 | c.330T>C p.T110= | Silent (SNP) | VAF 42/446 reads (9%) | called by muse, mutect2
- OR51A4 | c.864G>T p.T288= | Silent (SNP) | VAF 30/520 reads (6%) | catalogued as COSV66749974; called by muse, mutect2
- OR7C1 | c.471G>T p.L157= | Silent (SNP) | VAF 82/468 reads (18%) | called by muse, mutect2, varscan2
- P2RX7 | c.1659C>T p.Y553= | Silent (SNP) | VAF 94/584 reads (16%) | catalogued as rs200109812; called by muse, mutect2
- PCDHA13 | c.1899G>A p.T633= | Silent (SNP) | VAF 44/448 reads (10%) | catalogued as COSV56494744; called by muse, mutect2
- PCDHA6 | c.1962C>T p.H654= | Silent (SNP) | VAF 106/500 reads (21%) | catalogued as rs782097929; called by muse, mutect2, varscan2
- PCDHB6 | c.1341C>T p.P447= | Silent (SNP) | VAF 76/584 reads (13%) | catalogued as COSV50700539; called by muse, varscan2
- PDE6A | c.724C>T p.L242= | Silent (SNP) | VAF 49/261 reads (19%) | called by muse, mutect2, varscan2
- PKHD1 | c.8365T>C p.L2789= | Silent (SNP) | VAF 20/434 reads (5%) | called by muse, mutect2
- PLEKHM3 | c.1320C>T p.T440= | Silent (SNP) | VAF 49/322 reads (15%) | catalogued as rs759658615; called by muse, mutect2, varscan2
- PLXNB1 | c.636C>T p.S212= | Silent (SNP) | VAF 59/670 reads (9%) | catalogued as rs766350970; called by muse, mutect2
- PRAMEF4 | c.1104A>G p.Q368= | Silent (SNP) | VAF 74/638 reads (12%) | called by muse, mutect2, varscan2
- PREX2 | c.2838T>G p.S946= | Silent (SNP) | VAF 65/364 reads (18%) | catalogued as rs1361294223, COSV55789196; called by muse, mutect2, varscan2
- PRR23A | c.255G>A p.T85= | Silent (SNP) | VAF 17/394 reads (4%) | catalogued as COSV67214318; called by muse, mutect2
- PRRG3 | c.657C>T p.Y219= | Silent (SNP) | VAF 84/258 reads (33%) | catalogued as rs767174555, COSV64850660; called by muse, varscan2
- PRSS27 | c.18G>T p.A6= | Silent (SNP) | VAF 46/461 reads (10%) | called by mutect2, varscan2
- PTBP1 | c.1440C>T p.V480= (on ENST00000349038 / NM_031991.4; = p.V506= on NM_002819.5) | Silent (SNP) | VAF 75/334 reads (22%) | catalogued as rs144071881; called by muse, mutect2, varscan2
- QSER1 | c.2331C>T p.S777= (on ENST00000399302; = p.S906= on NM_001076786.3) | Silent (SNP) | VAF 13/363 reads (4%) | catalogued as rs1251858909; called by muse, mutect2
- RIMS1 | c.678T>A p.A226= | Silent (SNP) | VAF 41/391 reads (10%) | called by muse, mutect2, varscan2
- ROR2 | c.1707G>A p.S569= | Silent (SNP) | VAF 112/497 reads (23%) | catalogued as rs766805321, COSV65217795; ClinVar: likely benign; called by muse, mutect2
- SAFB2 | c.2127C>T p.R709= | Silent (SNP) | VAF 131/573 reads (23%) | catalogued as rs1412101633; called by muse, mutect2, varscan2
- SDAD1 | c.1122T>C p.L374= | Silent (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
- SEZ6L | c.2970G>A p.L990= | Silent (SNP) | VAF 21/197 reads (11%) | called by muse, mutect2, varscan2
- SH2D5 | c.783G>A p.L261= (on ENST00000444387 / NM_001103161.2; = p.L177= on NM_001103160.2) | Silent (SNP) | VAF 41/341 reads (12%) | catalogued as rs1284875876; called by muse, mutect2, varscan2
- SH3GL3 | c.267G>A p.T89= | Silent (SNP) | VAF 37/323 reads (11%) | catalogued as rs780585766; called by muse, mutect2, varscan2
- SLC7A9 | c.633C>T p.F211= | Silent (SNP) | VAF 88/501 reads (18%) | catalogued as rs372980958, CD010661, COSV50090007; called by muse, mutect2, varscan2
- SLCO6A1 | c.981T>C p.C327= | Silent (SNP) | VAF 28/357 reads (8%) | called by muse, mutect2
- SLITRK6 | c.1959T>G p.P653= | Silent (SNP) | VAF 48/368 reads (13%) | called by muse, mutect2, varscan2
- TEX13A | c.66C>T p.N22= | Silent (SNP) | VAF 82/294 reads (28%) | catalogued as rs781800251, COSV61157959; called by muse, mutect2, varscan2
- TEX38 | c.124T>C p.L42= | Silent (SNP) | VAF 27/297 reads (9%) | catalogued as rs934822807; called by muse, mutect2, varscan2
- TG | c.2433A>G p.E811= | Silent (SNP) | VAF 179/591 reads (30%) | catalogued as COSV55088246; called by muse, mutect2, varscan2
- TMTC2 | c.1443A>G p.E481= | Silent (SNP) | VAF 54/219 reads (25%) | catalogued as COSV58268096; called by muse, mutect2, varscan2
- TPO | c.327T>A p.T109= | Silent (SNP) | VAF 23/371 reads (6%) | called by muse, mutect2
- TRIM64B | c.1215A>C p.R405= | Silent (SNP) | VAF 86/783 reads (11%) | catalogued as rs202169525; called by muse, mutect2, varscan2
- TRIP10 | c.1575C>T p.P525= (on ENST00000313244 / NM_001288962.2; = p.P469= on NM_004240.4) | Silent (SNP) | VAF 80/398 reads (20%) | called by muse, mutect2, varscan2
- TRPC3 | c.414G>T p.L138= (on ENST00000379645 / NM_001366479.2; = p.L65= on NM_003305.2) | Silent (SNP) | VAF 36/392 reads (9%) | called by muse, mutect2
- TXNL1 | c.606A>T p.R202= | Silent (SNP) | VAF 34/159 reads (21%) | called by muse, mutect2, varscan2
- XIRP2 | c.3678A>G p.E1226= (on ENST00000628543; = p.E1401= on NM_152381.6) | Silent (SNP) | VAF 21/215 reads (10%) | catalogued as rs1268319895, COSV54696788, COSV54722905, COSV99739657; called by muse, mutect2
- ZNF679 | c.813A>G p.E271= | Silent (SNP) | VAF 122/281 reads (43%) | called by muse, mutect2, varscan2
- AC025419.1 | n.203+358dup | Intron (INS) | VAF 30/161 reads (19%) | catalogued as rs961552301; called by mutect2, varscan2
- AL132655.6 | chr20:58839607 G>A | 5'Flank (SNP) | VAF 20/674 reads (3%) | called by muse, mutect2
- ASIC2 | c.556-179757G>A | Intron (SNP) | VAF 109/618 reads (18%) | called by muse, mutect2, varscan2
- ATRIP | c.*1046C>A | 3'UTR (SNP) | VAF 68/514 reads (13%) | called by mutect2, varscan2
- CRMP1 | chr4:5892613 C>T | 5'Flank (SNP) | VAF 79/399 reads (20%) | called by muse, mutect2, varscan2
- DNAJB14 | c.306-1601G>A | Intron (SNP) | VAF 28/238 reads (12%) | called by muse, mutect2, varscan2
- FCGR3A | c.-44-98A>C | Intron (SNP) | VAF 26/392 reads (7%) | catalogued as rs1398917266; called by muse, mutect2
- FOLH1 | c.119-652G>T | Intron (SNP) | VAF 58/364 reads (16%) | called by mutect2, varscan2
- KCNQ1 | c.1514+25103del | Intron (DEL) | VAF 109/314 reads (35%) | called by mutect2, pindel, varscan2
- KIAA1958 | c.1172-27710C>T | Intron (SNP) | VAF 63/387 reads (16%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5759T>C | Intron (SNP) | VAF 43/392 reads (11%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5427T>A | Intron (SNP) | VAF 116/488 reads (24%) | called by muse, mutect2, varscan2
- NEB | c.8889+544G>T | Intron (SNP) | VAF 52/227 reads (23%) | called by mutect2, varscan2
- NPAP1L | n.414C>A | RNA (SNP) | VAF 24/123 reads (20%) | called by muse, mutect2, varscan2
- NPAP1L | n.413T>A | RNA (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
- SLC22A31 | c.-491C>T | 5'UTR (SNP) | VAF 64/658 reads (10%) | catalogued as rs1465862170; called by muse, mutect2
- SPATA8 | n.927C>T | RNA (SNP) | VAF 27/651 reads (4%) | catalogued as COSV60703947; called by muse, mutect2
- SYT14 | c.226+3164A>T | Intron (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- UNC13B | c.1168-13563T>A | Intron (SNP) | VAF 12/338 reads (4%) | called by muse, mutect2
